Somatic mutation profile of tumor specimen TCGA-B5-A0K1-01A (aliquot TCGA-B5-A0K1-01A-11W-A062-09) from TCGA case TCGA-B5-A0K1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 69.2 years (25,291 days).
Specimen TCGA-B5-A0K1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09eccd4e-b417-487d-92b3-78a5ff4337ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K1-10A (Blood Derived Normal), aliquot TCGA-B5-A0K1-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89c6a032-abf2-4793-a811-a6320a6a854d

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 110/293 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 145/376 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 158/501 reads (32%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- PTEN | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 46/98 reads (47%) | hotspot (GDC flag); catalogued as rs1057517809, CS1413088, COSV64290834, COSV64293694, COSV64298429; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATF2 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51371008; called by muse, mutect2
- BAZ1B | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59992295; called by muse, mutect2, varscan2
- BCORL1 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs750904043, COSV54399979; called by muse, mutect2, varscan2
- BMPR1B | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 78/195 reads (40%) | catalogued as COSV52779209; called by muse, mutect2, varscan2
- CDAN1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV51166625; called by muse, mutect2, varscan2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs778982759; called by mutect2, varscan2
- ERBB4 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs866138670, COSV53500723, COSV53502733; called by muse, mutect2, varscan2
- EXOC7 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV58742913; called by muse, mutect2, varscan2
- FAM234B | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as COSV52194983, COSV52195638; called by muse, mutect2, varscan2
- FAM9A | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV66813483; called by muse, mutect2, varscan2
- GBP1 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV65083916; called by muse, mutect2, varscan2
- H2BW1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs781962912, COSV54220644; called by muse, mutect2, varscan2
- HELZ | c.4150C>T p.Q1384* | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | catalogued as COSV62379340; called by muse, mutect2, varscan2
- LIMK2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs887228775, COSV59183153; called by muse, mutect2, varscan2
- MED13L | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 80/186 reads (43%) | catalogued as COSV56123763; called by muse, mutect2, varscan2
- MICU3 | c.803del p.N268Mfs*47 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | catalogued as rs199759760; called by mutect2, varscan2
- MMRN1 | c.1675A>C p.M559L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53339309; called by muse, mutect2, varscan2
- MTMR8 | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV66394908; called by muse, mutect2, varscan2
- NIN | c.5953G>A p.A1985T (on ENST00000382041 / NM_182946.1; = p.A1272T on NM_016350.4) | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55396558; called by muse, mutect2
- OR5D16 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65722340; called by muse, mutect2, varscan2
- PCDHB9 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as rs782116353, COSV53380994; called by muse, mutect2, varscan2
- PIK3R1 | c.1325T>G p.I442S (on ENST00000521381 / NM_181523.3; = p.I172S on NM_181504.4) | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV57132856; called by muse, varscan2
- PLCL1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs758051399, COSV70843741; called by muse, mutect2, varscan2
- RET | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs184498773, COSV60699984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHB | c.1191A>T p.E397D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66629585; called by muse, mutect2, varscan2
- SMARCB1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.14); catalogued as rs1223772419, COSV54098719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULF2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1273104352, COSV63417734; called by muse, mutect2, varscan2
- TMEM74B | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149321298, COSV67892082; called by muse, mutect2, varscan2
- TRAF5 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54823380; called by muse, varscan2
- TRIM9 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53619930; called by muse, mutect2, varscan2
- TRMT2A | c.1579G>C p.A527P | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV52814126; called by muse, mutect2, varscan2
- TSPO2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV55110788; called by muse, mutect2, varscan2
- ZFX | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 172/422 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs748417793, COSV58447078; called by muse, mutect2, varscan2
- ZNF304 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV56585228; called by muse, mutect2, varscan2
- ZNF568 | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs759744724, COSV61742060; called by muse, mutect2, varscan2
- ARID1A | c.2764_2765del p.G922Hfs*13 | Frame Shift Del (DEL) | VAF 64/205 reads (31%) | called by mutect2, pindel, varscan2
- LRP2 | c.5475_5476dup p.L1826Pfs*4 | Frame Shift Ins (INS) | VAF 60/165 reads (36%) | called by mutect2, pindel, varscan2
- ATRX | c.1032C>T p.S344= | Silent (SNP) | VAF 174/363 reads (48%) | catalogued as rs143491422, COSV64879104; ClinVar: benign; called by muse, mutect2, varscan2
- CYTH4 | c.76C>A p.R26= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV50633680, COSV50635001; called by muse, mutect2, varscan2
- DIO3 | c.615C>T p.D205= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs756925745, COSV63773981; called by muse, mutect2, varscan2
- KRTAP22-1 | c.30C>A p.G10= | Silent (SNP) | VAF 147/325 reads (45%) | catalogued as COSV58182534, COSV58183101; called by muse, mutect2, varscan2
- LDLR | c.282C>T p.D94= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV52944299; called by muse, mutect2, varscan2
- RGS9 | c.574C>A p.R192= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV52226906; called by muse, mutect2, varscan2
- SLC23A1 | c.315G>A p.P105= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs369474838; called by muse, mutect2
- TECPR2 | c.2496G>A p.L832= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as rs1471474819, COSV63971715; called by muse, mutect2, varscan2
- TSKS | c.1122C>T p.R374= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs542983208, COSV55873870; called by muse, mutect2, varscan2
- WDFY3 | c.9897C>T p.D3299= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV55706061; called by muse, mutect2, varscan2
- XYLT1 | c.1602G>A p.T534= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs138560456; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZAN | c.810G>A p.G270= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1046823186, COSV61811155; called by muse, mutect2, varscan2
- ZEB2 | c.2706C>T p.S902= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs754727621, COSV57959414; called by muse, mutect2
- SLC12A3 | c.2419+17C>T | Intron (SNP) | VAF 32/71 reads (45%) | catalogued as rs1047367698, COSV52636462; called by muse, mutect2, varscan2
